Somatic mutation profile of cancer-model specimen HCM-CSHL-0092-C25-85A (3D Organoid; aliquot HCM-CSHL-0092-C25-85A-01D-A786-36), derived from the primary tumor of HCMI case HCM-CSHL-0092-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 69.3 years (25,328 days).
Specimen HCM-CSHL-0092-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45c0c280-cfd7-42d6-b06f-19078c66c7a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0092-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-0092-C25-11A-11D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00fa190c-aecb-4cb7-9c58-b7d0b9856289

The open-access MAF lists 95 somatic variants for this specimen: 60 protein-altering or splice-affecting, 27 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 27, Intron 5, Nonsense Mutation 4, 5'UTR 2, Splice Region 2, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 119/248 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 107/153 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61684095, COSV61696676; called by muse, mutect2, varscan2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 377/377 reads (100%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs368706037; called by muse, mutect2, varscan2
- ACVR2A | c.1304A>T p.K435I | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54027870; called by muse, mutect2, varscan2
- ANGPTL6 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750994390, COSV53461722; called by muse, mutect2, varscan2
- ANKRD30BL | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 142/315 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs1416249576; called by muse, mutect2, varscan2
- ARHGAP39 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 36/597 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs770008645; called by muse, mutect2
- BDNF | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 271/616 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59233695; called by muse, mutect2, varscan2
- CDH4 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 48/382 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs1005735675, COSV64663856; called by muse, mutect2, varscan2
- CLDN8 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1364482689; called by muse, mutect2, varscan2
- CPNE4 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370033923; called by muse, mutect2, varscan2
- CRX | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 32/481 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778203784, COSV99704529; called by muse, mutect2
- CTNND2 | c.3188G>A p.R1063H | Missense Mutation (SNP) | VAF 218/422 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs113076343, COSV58908332, COSV58933321; called by muse, mutect2, varscan2
- DNAH5 | c.8138G>A p.R2713H | Missense Mutation (SNP) | VAF 178/395 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150536659; called by muse, mutect2, varscan2
- ELF3 | c.971_972dup p.T325* | Frame Shift Ins (INS) | VAF 15/81 reads (19%) | catalogued as COSV62840030; called by mutect2, pindel, varscan2
- FMN2 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs967255135; called by muse, mutect2, varscan2
- ITGA5 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.711); catalogued as rs773645556; called by muse, varscan2
- KIF26B | c.2644G>A p.D882N | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1232408087, COSV63637172; called by muse, mutect2, varscan2
- MSC | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as COSV57696776, COSV57697167; called by muse, mutect2, varscan2
- NEUROG3 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 285/598 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV54342438; called by muse, mutect2, varscan2
- NGF | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 224/498 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as rs201087374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRC3 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs753539558, COSV57090642; called by muse, mutect2
- NRCAM | c.1077G>A p.A359= (on ENST00000379028 / NM_001371124.1; = p.A353= on NM_005010.4 and 21 other RefSeq transcripts) | Splice Region (SNP) | VAF 12/170 reads (7%) | catalogued as rs772013992; called by muse, mutect2
- OBSL1 | c.3212C>T p.T1071I | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.305); catalogued as COSV54705704; called by mutect2, varscan2
- PCDHGA12 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.166); catalogued as COSV52766237; called by muse, mutect2
- PPP1R12C | c.1754C>G p.A585G | Missense Mutation (SNP) | VAF 126/302 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54738802; called by muse, mutect2, varscan2
- PRAMEF20 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 441/934 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as rs1234445065; called by muse, varscan2
- PRR19 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs972798619, COSV100003601; called by muse, mutect2, varscan2
- PRRG3 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 69/69 reads (100%) | catalogued as rs765253591; called by muse, mutect2, varscan2
- SBK1 | c.1153G>A p.V385M | Missense Mutation (SNP) | VAF 256/522 reads (49%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); catalogued as rs1192791653; called by muse, mutect2, varscan2
- SCN4A | c.3788C>T p.P1263L | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs767272792; called by muse, mutect2, varscan2
- SMC1B | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs754559505; called by muse, mutect2, varscan2
- SPATA19 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs139528428, COSV54483539; called by muse, mutect2, varscan2
- SV2A | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782011566, COSV100975223; called by muse, mutect2, varscan2
- TENM3 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs766457503, COSV69313834; called by muse, mutect2, varscan2
- U2AF2 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV50038179; called by muse, mutect2, varscan2
- VCAN | c.7034C>T p.T2345M | Missense Mutation (SNP) | VAF 206/431 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs765414121, COSV54116413; called by muse, mutect2, varscan2
- ZNF135 | c.1036C>T p.R346* (on ENST00000313434 / NM_001289401.2; = p.R358* on NM_003436.4) | Nonsense Mutation (SNP) | VAF 196/430 reads (46%) | catalogued as rs144688815, COSV100536601; called by muse, mutect2, varscan2
- A2ML1 | c.2680A>T p.S894C | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- C12orf65 | c.282+4G>T | Splice Region (SNP) | VAF 68/135 reads (50%) | called by muse, mutect2, varscan2
- ELAVL3 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, varscan2
- GALR2 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 219/493 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GGTLC1 | c.197C>A p.S66Y | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIAA1109 | c.3907C>G p.L1303V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- KLHL20 | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, varscan2
- KREMEN1 | c.220G>A p.G74R (on ENST00000407188; = p.G76R on NM_032045.5) | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTSS2 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 109/214 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MUC4 | c.15910G>A p.G5304S (on ENST00000463781 / NM_018406.7; = p.G1068S on NM_004532.6) | Missense Mutation (SNP) | VAF 99/215 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MUC5B | c.692T>A p.F231Y | Missense Mutation (SNP) | VAF 111/219 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PACRGL | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- SLC13A1 | c.1092_1097del p.D365_P366del | In Frame Del (DEL) | VAF 61/190 reads (32%) | called by mutect2, pindel, varscan2
- SLC25A48 | c.775G>T p.D259Y (on ENST00000650267; = p.D205Y on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SOBP | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 188/386 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.131); called by muse, varscan2
- SPO11 | c.147del p.S50Lfs*2 | Frame Shift Del (DEL) | VAF 25/55 reads (45%) | called by mutect2, pindel, varscan2
- SST | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TENT5B | c.383T>A p.L128Q | Missense Mutation (SNP) | VAF 90/92 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.23740C>A p.L7914I (on ENST00000591111; = p.L6987I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/137 reads (39%) | PolyPhen benign (0.013); called by muse, mutect2, varscan2
- WAC | c.1223del p.T408Mfs*9 | Frame Shift Del (DEL) | VAF 41/160 reads (26%) | called by mutect2, pindel, varscan2
- ZIC3 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 166/167 reads (99%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CAMK1G | c.1407G>A p.Q469= | Silent (SNP) | VAF 28/264 reads (11%) | called by muse, mutect2, varscan2
- CD79A | c.384G>A p.P128= | Silent (SNP) | VAF 74/166 reads (45%) | catalogued as rs782014534, COSV99701945; called by muse, mutect2, varscan2
- CEP350 | c.5319G>A p.L1773= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as COSV62602908; called by muse, mutect2, varscan2
- CHRNA1 | c.843C>A p.P281= (on ENST00000261007 / NM_001039523.3; = p.P256= on NM_000079.4) | Silent (SNP) | VAF 205/439 reads (47%) | called by muse, mutect2, varscan2
- CNMD | c.51C>T p.D17= | Silent (SNP) | VAF 128/245 reads (52%) | catalogued as COSV65033036; called by muse, mutect2, varscan2
- DPP3 | c.873G>A p.E291= | Silent (SNP) | VAF 47/102 reads (46%) | called by muse, mutect2, varscan2
- GPR4 | c.42C>T p.R14= | Silent (SNP) | VAF 69/150 reads (46%) | catalogued as rs753692265; called by muse, mutect2, varscan2
- KIAA0513 | c.705G>A p.S235= | Silent (SNP) | VAF 124/265 reads (47%) | catalogued as rs148794095; called by muse, mutect2, varscan2
- KLHDC8A | c.306C>T p.I102= | Silent (SNP) | VAF 78/156 reads (50%) | called by muse, mutect2, varscan2
- LCP2 | c.426C>T p.D142= | Silent (SNP) | VAF 95/196 reads (48%) | catalogued as rs561432915, COSV50450599; called by muse, mutect2, varscan2
- MRE11 | c.1479C>T p.L493= | Silent (SNP) | VAF 22/216 reads (10%) | catalogued as rs753325874; ClinVar: likely benign; called by muse, mutect2, varscan2
- MRGPRX3 | c.210G>A p.A70= | Silent (SNP) | VAF 92/178 reads (52%) | catalogued as rs749919475, COSV66934205; called by muse, mutect2, varscan2
- MTSS2 | c.1296C>T p.I432= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as rs1355099569; called by muse, mutect2
- MUC16 | c.31977G>A p.S10659= | Silent (SNP) | VAF 116/206 reads (56%) | catalogued as rs369258964, COSV67495078; called by muse, mutect2, varscan2
- NYAP2 | c.660G>A p.T220= | Silent (SNP) | VAF 95/210 reads (45%) | catalogued as rs752905382, COSV56003551; called by muse, mutect2, varscan2
- PCDHA13 | c.1233C>T p.S411= | Silent (SNP) | VAF 211/465 reads (45%) | called by muse, mutect2, varscan2
- PDZRN4 | c.243C>T p.C81= | Silent (SNP) | VAF 172/327 reads (53%) | catalogued as COSV68413605; called by muse, mutect2, varscan2
- PIM3 | c.639G>T p.P213= | Silent (SNP) | VAF 94/187 reads (50%) | called by muse, mutect2, varscan2
- PKHD1 | c.6649C>T p.L2217= | Silent (SNP) | VAF 53/443 reads (12%) | called by muse, mutect2, varscan2
- POU6F2 | c.165C>T p.S55= | Silent (SNP) | VAF 64/122 reads (52%) | catalogued as rs192309744, COSV101302775, COSV101302905; called by mutect2, varscan2
- RIMS1 | c.3871C>A p.R1291= | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as COSV53454539; called by muse, mutect2, varscan2
- SLC15A3 | c.618C>T p.I206= | Silent (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2
- SLITRK2 | c.2397T>C p.N799= | Silent (SNP) | VAF 86/109 reads (79%) | called by muse, mutect2, varscan2
- TLN2 | c.1125G>A p.E375= | Silent (SNP) | VAF 53/201 reads (26%) | called by muse, mutect2, varscan2
- TP63 | c.1890C>T p.S630= | Silent (SNP) | VAF 119/257 reads (46%) | called by muse, mutect2, varscan2
- UBQLN3 | c.537T>A p.G179= | Silent (SNP) | VAF 117/229 reads (51%) | called by muse, mutect2, varscan2
- VGLL2 | c.738C>T p.A246= | Silent (SNP) | VAF 17/184 reads (9%) | called by muse, mutect2
- CD81 | c.67-4267G>T | Intron (SNP) | VAF 121/308 reads (39%) | catalogued as rs1437518025; called by muse, mutect2, varscan2
- DZANK1 | c.379-77A>C | Intron (SNP) | VAF 114/240 reads (48%) | called by muse, mutect2, varscan2
- FNTA | c.-4C>T | 5'UTR (SNP) | VAF 87/139 reads (63%) | called by muse, mutect2, varscan2
- KMT5C | c.570+980G>A | Intron (SNP) | VAF 245/555 reads (44%) | called by muse, mutect2, varscan2
- RIMS2 | c.698+52954A>G | Intron (SNP) | VAF 85/203 reads (42%) | catalogued as rs572378309, COSV51655429; called by mutect2, varscan2
- RN7SKP78 | chr10:6144970 C>T | 5'Flank (SNP) | VAF 27/27 reads (100%) | called by muse, mutect2, varscan2
- TAPBP | c.-1C>T | 5'UTR (SNP) | VAF 163/324 reads (50%) | catalogued as rs1190044667; called by muse, mutect2, varscan2
- TTN | c.34265-3971G>T | Intron (SNP) | VAF 67/221 reads (30%) | called by muse, mutect2, varscan2
